Somatic mutation profile of tumor specimen ALCH-ADRZ-TTP1-A (aliquot ALCH-ADRZ-TTP1-A-1-0-D-A581-36) from ALCHEMIST case ALCH-ADRZ, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 61.6 years (22,493 days).
Specimen ALCH-ADRZ-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2b5705a2-caa5-4764-92fe-a612e2ae3b9e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-ADRZ-NB1-A (Blood Derived Normal), aliquot ALCH-ADRZ-NB1-A-1-0-D-A581-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6eb65500-1f72-4ec1-9bde-9652677fbba6

The open-access MAF lists 502 somatic variants for this specimen: 338 protein-altering or splice-affecting, 93 silent, 71 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 288, Silent 93, Intron 31, Nonsense Mutation 23, RNA 13, Frame Shift Del 12, 3'UTR 11, Splice Site 9, 5'UTR 8, 5'Flank 6, Splice Region 4, 3'Flank 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AC244197.3 | c.154G>T p.A52S | Missense Mutation (SNP) | VAF 124/270 reads (46%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); catalogued as CD031056; called by muse, mutect2, varscan2
- APOB | c.12889C>A p.R4297S | Missense Mutation (SNP) | VAF 175/631 reads (28%) | SIFT tolerated (0.95); PolyPhen benign (0.001); catalogued as COSV51959259; called by muse, mutect2, varscan2
- ARID1A | c.3793G>T p.G1265C | Missense Mutation (SNP) | VAF 52/194 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.846); catalogued as COSV61376024; called by muse, mutect2, varscan2
- ATRNL1 | c.620C>T p.S207L | Missense Mutation (SNP) | VAF 14/86 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.468); catalogued as rs368755603, COSV100746539; called by muse, varscan2
- ATRNL1 | c.3820A>G p.M1274V | Missense Mutation (SNP) | VAF 78/460 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.354); catalogued as COSV100368974; called by muse, mutect2, varscan2
- C12orf4 | c.179-1G>T p.X60_splice | Splice Site (SNP) | VAF 61/242 reads (25%) | catalogued as COSV99712783; called by muse, mutect2, varscan2
- CAMSAP2 | c.3965G>T p.R1322L (on ENST00000236925 / NM_001297707.2; = p.R1311L on NM_203459.3) | Missense Mutation (SNP) | VAF 128/380 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.655); catalogued as COSV52677953; called by muse, varscan2
- CCDC175 | c.1293A>C p.K431N | Missense Mutation (SNP) | VAF 33/522 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.618); catalogued as COSV104386284; called by muse, mutect2
- CMYA5 | c.8815G>T p.D2939Y | Missense Mutation (SNP) | VAF 66/327 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs762907572; called by muse, mutect2, varscan2
- CNGA3 | c.485A>G p.D162G | Missense Mutation (SNP) | VAF 41/344 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as CM014528, COSV99737326; called by muse, mutect2, varscan2
- CNNM1 | c.101G>T p.R34L | Missense Mutation (SNP) | VAF 22/127 reads (17%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.03); catalogued as COSV63201363; called by muse, mutect2, varscan2
- CNTNAP5 | c.3831G>T p.K1277N | Missense Mutation (SNP) | VAF 97/549 reads (18%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.941); catalogued as rs773483783; called by muse, mutect2, varscan2
- COL11A2 | c.439G>A p.G147S | Missense Mutation (SNP) | VAF 325/1427 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as rs1450967009; called by muse, mutect2, varscan2
- CSNK1A1 | c.602G>C p.R201P | Missense Mutation (SNP) | VAF 88/365 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV99939796; called by muse, mutect2, varscan2
- CTRB2 | c.52+6T>G | Splice Region (SNP) | VAF 86/537 reads (16%) | catalogued as rs770698393; called by muse, mutect2, varscan2
- DACH2 | c.561G>T p.L187F | Missense Mutation (SNP) | VAF 41/299 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.186); catalogued as COSV100913504; called by muse, mutect2, varscan2
- DLGAP2 | c.2263G>A p.G755R | Missense Mutation (SNP) | VAF 95/514 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1262675720, COSV101422952, COSV101423006; called by muse, mutect2, varscan2
- DNAH3 | c.255G>C p.L85F | Missense Mutation (SNP) | VAF 74/439 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.796); catalogued as COSV54504579, COSV54555352; called by muse, mutect2, varscan2
- DRC1 | c.1334C>T p.P445L | Missense Mutation (SNP) | VAF 79/675 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1440342812; called by muse, mutect2, varscan2
- DYSF | c.1078G>A p.D360N | Missense Mutation (SNP) | VAF 110/1482 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.967); catalogued as COSV99245646; called by muse, mutect2
- EED | c.29C>T p.P10L | Missense Mutation (SNP) | VAF 43/798 reads (5%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); catalogued as rs780894846, COSV99646514; called by muse, mutect2
- EFCC1 | c.595C>A p.R199S | Missense Mutation (SNP) | VAF 84/277 reads (30%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.539); catalogued as rs752305806; called by muse, mutect2, varscan2
- EGF | c.1336G>T p.G446* | Nonsense Mutation (SNP) | VAF 195/928 reads (21%) | catalogued as COSV99491234; called by muse, mutect2, varscan2
- EPHB2 | c.1861G>T p.V621F (on ENST00000400191 / NM_001309193.2; = p.V622F on NM_004442.7) | Missense Mutation (SNP) | VAF 214/630 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101007558; called by muse, mutect2, varscan2
- ERBB2 | c.1447G>C p.D483H | Missense Mutation (SNP) | VAF 107/624 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.014); catalogued as COSV54087680; called by muse, mutect2, varscan2
- FANCL | c.869T>A p.I290N | Missense Mutation (SNP) | VAF 88/1028 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.771); catalogued as rs761259325; called by muse, mutect2
- FER1L5 | c.3224G>A p.R1075K (on ENST00000623019; = p.R1048K on NM_001293083.2) | Missense Mutation (SNP) | VAF 19/446 reads (4%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as rs1266249005; called by muse, mutect2
- FLRT2 | c.1063A>G p.M355V | Missense Mutation (SNP) | VAF 43/200 reads (22%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs988486068, COSV58143368; called by muse, mutect2, varscan2
- GATA2 | c.708G>A p.M236I | Missense Mutation (SNP) | VAF 39/427 reads (9%) | SIFT tolerated (0.67); PolyPhen benign (0.001); catalogued as COSV100351304; called by muse, mutect2
- HCN4 | c.994C>T p.R332W | Missense Mutation (SNP) | VAF 213/795 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as rs141185786; called by muse, mutect2, varscan2
- HHIP | c.1861G>A p.G621R | Missense Mutation (SNP) | VAF 71/354 reads (20%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.999); catalogued as COSV56841886; called by muse, mutect2, varscan2
- HIPK2 | c.763G>C p.A255P | Missense Mutation (SNP) | VAF 27/376 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61228379; called by muse, mutect2
- HNF4G | c.565A>G p.M189V (on ENST00000354370 / NM_001330561.2; = p.M236V on NM_004133.5) | Missense Mutation (SNP) | VAF 62/203 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.261); catalogued as rs1293682861; called by muse, mutect2, varscan2
- HOXA7 | c.311C>T p.T104M | Missense Mutation (SNP) | VAF 86/259 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.335); catalogued as rs754637278; called by muse, mutect2, varscan2
- HTR3B | c.480T>A p.Y160* | Nonsense Mutation (SNP) | VAF 54/575 reads (9%) | catalogued as rs564311899; called by muse, mutect2
- HUWE1 | c.8669C>T p.P2890L | Missense Mutation (SNP) | VAF 45/279 reads (16%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0); catalogued as rs1556930398; called by muse, mutect2, varscan2
- IGLV4-69 | c.70C>G p.L24V | Missense Mutation (SNP) | VAF 41/187 reads (22%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.472); catalogued as rs755291178; called by muse, mutect2, varscan2
- INPP5F | c.1496G>T p.R499L | Missense Mutation (SNP) | VAF 77/421 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.05); catalogued as rs775019768, COSV62820038; called by muse, mutect2, varscan2
- JRK | c.92G>A p.R31H | Missense Mutation (SNP) | VAF 150/1339 reads (11%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.97); catalogued as rs782225462; called by muse, mutect2, varscan2
- KCNC2 | c.899G>A p.R300H | Missense Mutation (SNP) | VAF 20/467 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV54368719; called by muse, mutect2
- KCNC4 | c.1223G>T p.R408M | Missense Mutation (SNP) | VAF 166/598 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.361); catalogued as COSV63926610; called by muse, mutect2, varscan2
- KCNH7 | c.3536T>C p.V1179A | Missense Mutation (SNP) | VAF 113/431 reads (26%) | SIFT tolerated, low confidence (0.73); PolyPhen benign (0.003); catalogued as rs942531071; called by muse, mutect2, varscan2
- KDM4B | c.1726G>A p.G576S | Missense Mutation (SNP) | VAF 24/294 reads (8%) | SIFT tolerated (0.68); PolyPhen benign (0.015); catalogued as rs773359252; called by muse, mutect2
- KEAP1 | c.704A>T p.D235V | Missense Mutation (SNP) | VAF 121/353 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV50660006; called by muse, mutect2, varscan2
- KIAA1549L | c.2737G>T p.D913Y (on ENST00000321505; = p.D1210Y on NM_012194.3) | Missense Mutation (SNP) | VAF 300/883 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs12807537; called by muse, mutect2, varscan2
- KIF4A | c.1186G>C p.V396L | Missense Mutation (SNP) | VAF 112/277 reads (40%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs1334183190; called by muse, mutect2, varscan2
- KRT83 | c.844G>A p.E282K | Missense Mutation (SNP) | VAF 215/1082 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.272); catalogued as rs376193228; called by muse, mutect2, varscan2
- LAMB4 | c.1906G>A p.V636I | Missense Mutation (SNP) | VAF 132/365 reads (36%) | SIFT tolerated (0.27); PolyPhen benign (0.009); catalogued as rs749066891; called by muse, mutect2, varscan2
- LARS1 | c.3025G>T p.D1009Y (on ENST00000394434 / NM_020117.11; = p.D982Y on NM_016460.3) | Missense Mutation (SNP) | VAF 80/472 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.894); catalogued as rs559313290, COSV50973983; called by muse, mutect2, varscan2
- LEPR | c.526C>T p.P176S | Missense Mutation (SNP) | VAF 137/529 reads (26%) | SIFT tolerated (0.82); PolyPhen benign (0.007); catalogued as COSV60751345; called by muse, mutect2, varscan2
- LRIT1 | c.338G>C p.R113P | Missense Mutation (SNP) | VAF 43/313 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs767968938; called by muse, mutect2, varscan2
- LRP2 | c.13167C>A p.C4389* | Nonsense Mutation (SNP) | VAF 175/812 reads (22%) | catalogued as COSV55549982; called by muse, mutect2, varscan2
- LRRC30 | c.636G>C p.Q212H | Missense Mutation (SNP) | VAF 93/414 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.862); catalogued as COSV67302211; called by muse, mutect2, varscan2
- LRRC32 | c.1499del p.G500Afs*4 | Frame Shift Del (DEL) | VAF 26/226 reads (12%) | catalogued as COSV99476578; called by mutect2, pindel, varscan2
- LRRC7 | c.4298C>G p.P1433R (on ENST00000651989 / NM_001370785.2; = p.P1353R on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 108/429 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0.076); catalogued as COSV50647126; called by muse, mutect2, varscan2
- LRRC8A | c.2270C>T p.T757M | Missense Mutation (SNP) | VAF 42/361 reads (12%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.577); catalogued as rs557710052, COSV99396123; called by muse, mutect2, varscan2
- MROH2B | c.4432C>A p.Q1478K | Missense Mutation (SNP) | VAF 80/449 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.035); catalogued as COSV68189368; called by muse, mutect2, varscan2
- MUC15 | c.206C>T p.A69V | Missense Mutation (SNP) | VAF 148/532 reads (28%) | SIFT tolerated (0.38); PolyPhen benign (0.013); catalogued as rs200191911; called by muse, mutect2, varscan2
- NAV3 | c.2233G>C p.G745R | Missense Mutation (SNP) | VAF 121/572 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57097905; called by muse, mutect2, varscan2
- NIBAN1 | c.257G>C p.W86S | Missense Mutation (SNP) | VAF 35/425 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV62286307; called by muse, mutect2
- NKD2 | c.173C>T p.P58L | Missense Mutation (SNP) | VAF 45/275 reads (16%) | SIFT tolerated (0.3); PolyPhen benign (0.005); catalogued as rs1468962900; called by muse, mutect2, varscan2
- NR4A2 | c.983T>C p.M328T | Missense Mutation (SNP) | VAF 244/1616 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100277196; called by muse, mutect2, varscan2
- NXPE1 | c.393G>T p.R131S | Missense Mutation (SNP) | VAF 105/463 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.904); catalogued as COSV52628309; called by muse, mutect2, varscan2
- OR2T11 | c.356G>A p.C119Y | Missense Mutation (SNP) | VAF 90/385 reads (23%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs140753661; called by muse, mutect2, varscan2
- OR4C46 | c.531T>A p.C177* | Nonsense Mutation (SNP) | VAF 52/444 reads (12%) | catalogued as rs755373479, COSV100061148; called by muse, mutect2, varscan2
- P2RX6 | c.736C>T p.L246F | Missense Mutation (SNP) | VAF 101/602 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.757); catalogued as COSV60384284; called by muse, mutect2, varscan2
- PABPC4L | c.1064G>T p.R355L | Missense Mutation (SNP) | VAF 40/631 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.41); catalogued as COSV69930491; called by muse, mutect2
- PBRM1 | c.356T>A p.L119H | Missense Mutation (SNP) | VAF 187/623 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV56263716, COSV56271422; called by muse, mutect2, varscan2
- PDE6C | c.800C>A p.T267K | Missense Mutation (SNP) | VAF 141/783 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs199926911, COSV65116517; called by muse, mutect2, varscan2
- PGM2 | c.50A>G p.Q17R | Missense Mutation (SNP) | VAF 45/529 reads (9%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as rs1415827251; called by muse, mutect2
- PHLDB2 | c.2380A>G p.I794V (on ENST00000393925 / NM_001134439.2; = p.I751V on NM_145753.2) | Missense Mutation (SNP) | VAF 52/201 reads (26%) | SIFT deleterious (0.05); PolyPhen benign (0.017); catalogued as rs757058180; called by muse, mutect2, varscan2
- PKD1 | c.3797G>C p.R1266P | Missense Mutation (SNP) | VAF 115/504 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.772); catalogued as COSV99239263; called by muse, mutect2, varscan2
- PKHD1 | c.9532G>T p.G3178C | Missense Mutation (SNP) | VAF 301/1308 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as CM051178; called by muse, mutect2, varscan2
- PNLIPRP3 | c.961C>A p.P321T | Missense Mutation (SNP) | VAF 148/739 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.688); catalogued as rs1334021707, COSV65049711; called by muse, mutect2, varscan2
- POTEI | c.268G>T p.A90S | Missense Mutation (SNP) | VAF 194/1330 reads (15%) | SIFT tolerated, low confidence (0.15); PolyPhen possibly damaging (0.739); catalogued as rs28450341, COSV71576069; called by muse, mutect2, varscan2
- PPP1R10 | c.105C>T p.F35= | Splice Region (SNP) | VAF 152/473 reads (32%) | catalogued as rs1462773492, COSV64739173, COSV64739800; called by muse, mutect2, varscan2
- PRG4 | c.938T>C p.I313T | Missense Mutation (SNP) | VAF 254/1757 reads (14%) | SIFT tolerated (0.35); PolyPhen benign (0.033); catalogued as rs1408821793, COSV66600175; called by muse, mutect2, varscan2
- PXDN | c.2021G>A p.R674Q | Missense Mutation (SNP) | VAF 34/495 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs746336803, COSV53241106; called by muse, mutect2
- RAD51AP2 | c.2280C>A p.S760R | Missense Mutation (SNP) | VAF 30/354 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.055); catalogued as rs748613214; called by muse, mutect2
- RBM45 | c.82A>G p.I28V | Missense Mutation (SNP) | VAF 179/777 reads (23%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs1447463836; called by muse, mutect2, varscan2
- RIDA | c.91A>G p.I31V | Missense Mutation (SNP) | VAF 150/555 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs769492200; called by muse, mutect2, varscan2
- RUBCNL | c.1616G>A p.C539Y | Missense Mutation (SNP) | VAF 160/586 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs774620986; called by muse, mutect2, varscan2
- SBF1 | c.4634G>A p.R1545H | Missense Mutation (SNP) | VAF 62/856 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs750794912; called by muse, mutect2
- SDSL | c.854C>A p.S285* | Nonsense Mutation (SNP) | VAF 55/315 reads (17%) | catalogued as COSV61885466; called by muse, mutect2, varscan2
- SHANK2 | c.3901G>A p.D1301N | Missense Mutation (SNP) | VAF 100/1612 reads (6%) | SIFT tolerated (0.98); PolyPhen benign (0.001); catalogued as rs371656531; called by muse, mutect2
- SLC27A3 | c.1382C>T p.S461F (on ENST00000271857; = p.S333F on NM_024330.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 74/625 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1183982767; called by muse, mutect2, varscan2
- SLC35B4 | c.876C>A p.F292L | Missense Mutation (SNP) | VAF 321/938 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as rs1348610623; called by muse, mutect2, varscan2
- SLC5A4 | c.304G>T p.E102* | Nonsense Mutation (SNP) | VAF 40/360 reads (11%) | catalogued as COSV99831610, COSV99831864; called by muse, mutect2, varscan2
- SLIT1 | c.1567G>T p.V523L | Missense Mutation (SNP) | VAF 55/424 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.019); catalogued as COSV56591409; called by muse, mutect2, varscan2
- SORCS3 | c.2591G>T p.G864V | Missense Mutation (SNP) | VAF 89/494 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63793627; called by muse, mutect2, varscan2
- SORCS3 | c.3007C>A p.Q1003K | Missense Mutation (SNP) | VAF 37/227 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.109); catalogued as COSV63794243; called by muse, mutect2, varscan2
- SPTA1 | c.2820G>T p.K940N | Missense Mutation (SNP) | VAF 119/1161 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs759064678, COSV63756277, COSV63759629; called by muse, mutect2, varscan2
- SPTB | c.2300C>A p.S767Y | Missense Mutation (SNP) | VAF 101/367 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV67630295; called by muse, mutect2, varscan2
- SSH2 | c.105G>C p.R35S | Missense Mutation (SNP) | VAF 81/665 reads (12%) | SIFT tolerated (0.21); PolyPhen benign (0.021); catalogued as COSV52180374; called by muse, varscan2
- STAM | c.1430C>T p.A477V | Missense Mutation (SNP) | VAF 170/665 reads (26%) | SIFT tolerated (0.49); PolyPhen benign (0.001); catalogued as rs370940096; called by muse, mutect2, varscan2
- SYT12 | c.1070C>A p.S357* | Nonsense Mutation (SNP) | VAF 180/639 reads (28%) | catalogued as COSV101210916, COSV67355238; called by muse, mutect2, varscan2
- TBC1D17 | c.473G>A p.R158H | Missense Mutation (SNP) | VAF 30/427 reads (7%) | SIFT tolerated (0.32); PolyPhen benign (0.028); catalogued as rs912616149, COSV99680486; called by muse, mutect2
- TDRD9 | c.3620G>A p.G1207E | Missense Mutation (SNP) | VAF 120/330 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.807); catalogued as COSV59153976; called by muse, varscan2
- TIAM1 | c.2006G>A p.R669H | Missense Mutation (SNP) | VAF 19/135 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.413); catalogued as rs372207705; called by muse, mutect2, varscan2
- TNS2 | c.2885C>T p.S962L (on ENST00000314250 / NM_170754.4; = p.S972L on NM_015319.2) | Missense Mutation (SNP) | VAF 25/228 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0.01); catalogued as rs1218467688; called by muse, mutect2, varscan2
- TP53 | c.527dup p.C176Wfs*5 | Frame Shift Ins (INS) | VAF 147/566 reads (26%) | catalogued as COSV52756284, COSV99037144, COSV99403879; called by mutect2, pindel, varscan2
- TRIO | c.3421G>A p.V1141M | Missense Mutation (SNP) | VAF 61/428 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1217013472; called by muse, mutect2, varscan2
- TSPYL2 | c.1279G>T p.A427S | Missense Mutation (SNP) | VAF 198/424 reads (47%) | SIFT tolerated, low confidence (0.99); PolyPhen benign (0.005); catalogued as COSV64921601; called by muse, mutect2, varscan2
- WDR64 | c.1460G>T p.G487V | Missense Mutation (SNP) | VAF 66/591 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63794999; called by muse, mutect2, varscan2
- ZIC3 | c.897G>A p.W299* | Nonsense Mutation (SNP) | VAF 148/344 reads (43%) | catalogued as COSV54973612; called by muse, mutect2, varscan2
- ZNF107 | c.1271C>G p.S424C | Missense Mutation (SNP) | VAF 37/330 reads (11%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.934); catalogued as COSV61329197; called by muse, mutect2, varscan2
- ZNF318 | c.5072del p.P1691Qfs*39 | Frame Shift Del (DEL) | VAF 50/447 reads (11%) | catalogued as COSV58937677; called by mutect2, pindel, varscan2
- ZNF623 | c.257G>T p.W86L | Missense Mutation (SNP) | VAF 98/413 reads (24%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.755); catalogued as COSV101513568; called by muse, mutect2, varscan2
- ZNF680 | c.898C>T p.H300Y | Missense Mutation (SNP) | VAF 35/478 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.453); catalogued as COSV100549069; called by muse, mutect2
- ZNF804B | c.1358C>G p.T453S | Missense Mutation (SNP) | VAF 24/535 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.722); catalogued as COSV60849909; called by muse, mutect2
- ZNF804B | c.2974G>C p.D992H | Missense Mutation (SNP) | VAF 87/370 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.31); catalogued as COSV60819598; called by muse, mutect2, varscan2
- ZNF831 | c.1139G>T p.G380V | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.503); catalogued as COSV64044433; called by muse, mutect2, varscan2
- ZP4 | c.226T>A p.W76R | Missense Mutation (SNP) | VAF 124/748 reads (17%) | SIFT tolerated (0.38); PolyPhen benign (0.132); catalogued as COSV63912247; called by muse, mutect2, varscan2
- ADAMTS20 | c.4153T>C p.C1385R | Missense Mutation (SNP) | VAF 72/336 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ANK2 | c.1387C>G p.R463G | Missense Mutation (SNP) | VAF 80/997 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); called by muse, mutect2
- ANKRD44 | c.1792G>T p.E598* | Nonsense Mutation (SNP) | VAF 170/1084 reads (16%) | called by muse, mutect2, varscan2
- AP002512.3 | c.692A>T p.N231I | Missense Mutation (SNP) | VAF 48/397 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- AP3B1 | c.3175A>G p.T1059A | Missense Mutation (SNP) | VAF 145/646 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.437); called by muse, mutect2, varscan2
- AQR | c.2203G>A p.V735I | Missense Mutation (SNP) | VAF 77/243 reads (32%) | SIFT tolerated (0.39); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ARHGAP22 | c.1781_1782del p.R594Pfs*11 | Frame Shift Del (DEL) | VAF 74/474 reads (16%) | called by pindel, varscan2
- ARHGAP22 | c.1546T>C p.S516P | Missense Mutation (SNP) | VAF 11/116 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); called by muse, mutect2, varscan2
- ARHGAP22 | c.898G>A p.V300I | Missense Mutation (SNP) | VAF 71/1098 reads (6%) | SIFT tolerated (0.22); PolyPhen benign (0.05); called by muse, mutect2
- ARNT2 | c.169G>T p.G57C | Missense Mutation (SNP) | VAF 121/434 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); called by muse, mutect2, varscan2
- ARVCF | c.793_797del p.T265Qfs*5 | Frame Shift Del (DEL) | VAF 66/303 reads (22%) | called by mutect2, pindel, varscan2
- ASH1L | c.5480A>G p.N1827S | Missense Mutation (SNP) | VAF 62/576 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- ASNSD1 | c.1736G>A p.G579D | Missense Mutation (SNP) | VAF 46/956 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ASPM | c.7327G>C p.A2443P | Missense Mutation (SNP) | VAF 162/1532 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- B3GNT7 | c.1012G>T p.G338C | Missense Mutation (SNP) | VAF 92/436 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.8); called by muse, mutect2, varscan2
- B4GALNT3 | c.584G>T p.W195L | Missense Mutation (SNP) | VAF 103/510 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- BBS12 | c.845G>C p.S282T | Missense Mutation (SNP) | VAF 39/348 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- BIRC6 | c.6584del p.P2195Lfs*2 | Frame Shift Del (DEL) | VAF 101/482 reads (21%) | called by mutect2, pindel, varscan2
- C10orf82 | c.109C>A p.H37N | Missense Mutation (SNP) | VAF 42/206 reads (20%) | SIFT tolerated (0.58); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- C10orf82 | c.108C>A p.N36K | Missense Mutation (SNP) | VAF 40/201 reads (20%) | SIFT tolerated (0.48); PolyPhen benign (0.098); called by muse, mutect2, varscan2
- C18orf54 | c.307A>T p.K103* | Nonsense Mutation (SNP) | VAF 46/166 reads (28%) | called by muse, mutect2
- C9orf131 | c.1369C>A p.Q457K | Missense Mutation (SNP) | VAF 105/306 reads (34%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.67); called by muse, mutect2, varscan2
- CABP5 | c.76G>C p.G26R | Missense Mutation (SNP) | VAF 29/260 reads (11%) | SIFT tolerated (0.47); PolyPhen benign (0); called by muse, mutect2, varscan2
- CACNA1E | c.2138C>G p.T713S | Missense Mutation (SNP) | VAF 107/677 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- CAPZA3 | c.466G>T p.E156* | Nonsense Mutation (SNP) | VAF 74/357 reads (21%) | called by muse, mutect2, varscan2
- CASS4 | c.952A>T p.R318* | Nonsense Mutation (SNP) | VAF 256/823 reads (31%) | called by muse, mutect2, varscan2
- CBFA2T3 | c.179C>T p.S60L | Missense Mutation (SNP) | VAF 59/355 reads (17%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- CCDC149 | c.1304G>T p.G435V (on ENST00000635206 / NM_001330643.2; = p.G424V on NM_173463.5) | Missense Mutation (SNP) | VAF 81/864 reads (9%) | SIFT tolerated, low confidence (0.12); PolyPhen possibly damaging (0.543); called by muse, mutect2
- CCDC168 | c.5333C>G p.T1778R | Missense Mutation (SNP) | VAF 120/381 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.326); called by muse, varscan2
- CCDC28A | c.112T>C p.S38P | Missense Mutation (SNP) | VAF 220/710 reads (31%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.844); called by muse, mutect2, varscan2
- CCDC85A | c.1201G>T p.G401W | Missense Mutation (SNP) | VAF 30/118 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.04); called by muse, mutect2
- CD163L1 | c.2566C>A p.L856I | Missense Mutation (SNP) | VAF 262/1245 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.781); called by muse, mutect2, varscan2
- CD22 | c.2415C>A p.G805= | Splice Region (SNP) | VAF 136/754 reads (18%) | called by muse, mutect2, varscan2
- CD6 | c.1240G>A p.G414S | Missense Mutation (SNP) | VAF 56/816 reads (7%) | SIFT tolerated (0.49); PolyPhen benign (0.227); called by muse, mutect2
- CDC42EP5 | c.106G>C p.V36L | Missense Mutation (SNP) | VAF 70/177 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.862); called by muse, mutect2, varscan2
- CDH11 | c.893G>A p.G298E | Missense Mutation (SNP) | VAF 30/453 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2
- CHD9 | c.3377G>T p.G1126V | Missense Mutation (SNP) | VAF 26/107 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CHRM3 | c.1063G>A p.E355K | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- CNTNAP2 | c.3649T>C p.S1217P | Missense Mutation (SNP) | VAF 94/668 reads (14%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.642); called by muse, mutect2, varscan2
- COCH | c.343T>A p.C115S (on ENST00000216361 / NM_001347720.1; = p.C50S on NM_004086.3) | Missense Mutation (SNP) | VAF 192/849 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CPNE9 | c.164G>C p.R55P | Missense Mutation (SNP) | VAF 166/553 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.685); called by muse, mutect2, varscan2
- CSMD3 | c.4492C>T p.L1498F (on ENST00000297405 / NM_001363185.1; = p.L1394F on NM_052900.3) | Missense Mutation (SNP) | VAF 145/650 reads (22%) | SIFT tolerated (1); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- CWH43 | c.607G>T p.G203C | Missense Mutation (SNP) | VAF 39/417 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CWH43 | c.608G>T p.G203V | Missense Mutation (SNP) | VAF 39/415 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CXCR4 | c.818G>T p.G273V | Missense Mutation (SNP) | VAF 159/841 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.837); called by muse, mutect2, varscan2
- CYP11A1 | c.231C>A p.H77Q | Missense Mutation (SNP) | VAF 186/605 reads (31%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.724); called by muse, mutect2, varscan2
- DAOA | c.121C>A p.L41I | Missense Mutation (SNP) | VAF 62/311 reads (20%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.781); called by muse, mutect2, varscan2
- DGKI | c.1681A>G p.K561E | Missense Mutation (SNP) | VAF 113/332 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- DGKK | c.488C>T p.P163L | Missense Mutation (SNP) | VAF 86/278 reads (31%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0); called by muse, mutect2, varscan2
- DHODH | c.475A>T p.R159W | Missense Mutation (SNP) | VAF 238/1273 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- DISP1 | c.139A>G p.R47G | Missense Mutation (SNP) | VAF 186/861 reads (22%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); called by muse, mutect2, varscan2
- DNAH10 | c.7209C>A p.F2403L (on ENST00000409039; = p.F2342L on NM_207437.3) | Missense Mutation (SNP) | VAF 60/935 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2
- DNAH5 | c.3721A>G p.K1241E | Missense Mutation (SNP) | VAF 106/743 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- DNMBP | c.4694A>G p.Y1565C | Missense Mutation (SNP) | VAF 94/397 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DOCK10 | c.499_505del p.S167Rfs*29 | Frame Shift Del (DEL) | VAF 52/376 reads (14%) | called by mutect2, pindel, varscan2
- DPP8 | c.1546A>C p.S516R (on ENST00000341861 / NM_001320875.2; = p.S500R on NM_017743.6) | Missense Mutation (SNP) | VAF 115/424 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- DZIP3 | c.3256C>T p.P1086S | Missense Mutation (SNP) | VAF 66/352 reads (19%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.589); called by muse, mutect2, varscan2
- EEA1 | c.4083T>A p.C1361* | Nonsense Mutation (SNP) | VAF 190/929 reads (20%) | called by muse, mutect2, varscan2
- EEF2K | c.1324G>C p.G442R | Missense Mutation (SNP) | VAF 47/290 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- EFCAB5 | c.2904C>A p.S968R | Missense Mutation (SNP) | VAF 22/454 reads (5%) | SIFT deleterious (0.05); PolyPhen benign (0.107); called by muse, mutect2
- ELFN2 | c.336C>A p.Y112* | Nonsense Mutation (SNP) | VAF 100/483 reads (21%) | called by muse, mutect2, varscan2
- EMB | c.810G>T p.E270D | Missense Mutation (SNP) | VAF 60/532 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- EPSTI1 | c.541G>T p.A181S | Missense Mutation (SNP) | VAF 52/294 reads (18%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.475); called by muse, mutect2, varscan2
- ERO1B | c.1332T>A p.N444K | Missense Mutation (SNP) | VAF 36/282 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, varscan2
- FER1L5 | c.267G>C p.L89F | Missense Mutation (SNP) | VAF 105/560 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- FGA | c.2342A>G p.N781S | Missense Mutation (SNP) | VAF 12/132 reads (9%) | SIFT tolerated (0.79); PolyPhen benign (0.018); called by muse, mutect2
- FGF12 | c.200-2A>G p.X67_splice (on ENST00000454309 / NM_021032.5; = p.X5_splice on NM_004113.6) | Splice Site (SNP) | VAF 37/315 reads (12%) | called by muse, mutect2, varscan2
- FGFR2 | c.2113C>T p.P705S | Missense Mutation (SNP) | VAF 77/770 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FRMD6 | c.79T>A p.S27T | Missense Mutation (SNP) | VAF 66/716 reads (9%) | SIFT tolerated (0.34); PolyPhen benign (0.034); called by muse, mutect2
- FUT9 | c.260A>G p.N87S | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.474); called by muse, mutect2, varscan2
- FXR1 | c.847G>C p.E283Q | Missense Mutation (SNP) | VAF 69/484 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.925); called by muse, mutect2, varscan2
- GLI3 | c.3184T>C p.S1062P | Missense Mutation (SNP) | VAF 80/503 reads (16%) | SIFT tolerated (0.21); PolyPhen benign (0); called by muse, mutect2, varscan2
- GPI | c.1006C>T p.H336Y | Missense Mutation (SNP) | VAF 42/1082 reads (4%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.213); called by muse, mutect2
- GPR12 | c.277G>A p.A93T | Missense Mutation (SNP) | VAF 105/580 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HAP1 | c.164C>G p.T55S | Missense Mutation (SNP) | VAF 16/118 reads (14%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- HEATR5A | c.4664A>G p.Y1555C | Missense Mutation (SNP) | VAF 30/391 reads (8%) | SIFT tolerated (0.15); PolyPhen benign (0); called by muse, mutect2
- HLA-DQA2 | c.166G>C p.E56Q | Missense Mutation (SNP) | VAF 62/595 reads (10%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.99); called by muse, varscan2
- HSPA1L | c.1574A>C p.E525A | Missense Mutation (SNP) | VAF 87/315 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.745); called by muse, mutect2, varscan2
- IFI44L | c.421A>T p.K141* | Nonsense Mutation (SNP) | VAF 70/193 reads (36%) | called by muse, mutect2, varscan2
- IKZF5 | c.419G>A p.C140Y | Missense Mutation (SNP) | VAF 92/636 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- INTS3 | c.948G>T p.M316I | Missense Mutation (SNP) | VAF 45/417 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- IQGAP2 | c.4596G>T p.K1532N | Missense Mutation (SNP) | VAF 60/290 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.224); called by muse, mutect2, varscan2
- IQGAP3 | c.1072G>T p.E358* | Nonsense Mutation (SNP) | VAF 34/387 reads (9%) | called by muse, mutect2
- IRAK3 | c.1045G>T p.G349W | Missense Mutation (SNP) | VAF 194/837 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- ITGAV | c.107A>G p.D36G | Missense Mutation (SNP) | VAF 151/1076 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- JMJD1C | c.1381A>C p.I461L | Missense Mutation (SNP) | VAF 105/689 reads (15%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0); called by muse, mutect2, varscan2
- KCNJ14 | c.628G>C p.D210H | Missense Mutation (SNP) | VAF 30/94 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KCNK10 | c.1133G>T p.R378L | Missense Mutation (SNP) | VAF 79/300 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.667); called by muse, mutect2, varscan2
- KCNK16 | c.856G>A p.G286S | Missense Mutation (SNP) | VAF 49/313 reads (16%) | SIFT tolerated (0.78); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- KIAA1109 | c.6926A>G p.E2309G | Missense Mutation (SNP) | VAF 109/622 reads (18%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- KIAA1549L | c.1203T>A p.S401R (on ENST00000321505; = p.S698R on NM_012194.3) | Missense Mutation (SNP) | VAF 126/455 reads (28%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- KIF3C | c.2375A>G p.H792R | Missense Mutation (SNP) | VAF 33/268 reads (12%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- KLHL36 | c.107_122del p.L36Pfs*49 | Frame Shift Del (DEL) | VAF 26/202 reads (13%) | called by mutect2, pindel
- KNDC1 | c.631A>T p.S211C | Missense Mutation (SNP) | VAF 33/203 reads (16%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.712); called by muse, mutect2, varscan2
- LAMA1 | c.2791C>A p.Q931K | Missense Mutation (SNP) | VAF 148/700 reads (21%) | SIFT tolerated (0.44); PolyPhen benign (0.011); called by muse, varscan2
- LGI1 | c.553G>C p.V185L | Missense Mutation (SNP) | VAF 152/926 reads (16%) | SIFT tolerated (0.38); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- LIPJ | c.131-1_131dup p.X44_splice | Splice Site (INS) | VAF 47/285 reads (16%) | called by mutect2, pindel, varscan2
- LRCH4 | c.1039+1G>A p.X347_splice | Splice Site (SNP) | VAF 27/315 reads (9%) | called by muse, mutect2
- LRRC45 | c.70del p.L24Cfs*19 | Frame Shift Del (DEL) | VAF 131/449 reads (29%) | called by mutect2, pindel, varscan2
- LRRTM3 | c.1251C>A p.F417L | Missense Mutation (SNP) | VAF 127/707 reads (18%) | SIFT tolerated (0.29); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- LRRTM4 | c.1597C>G p.P533A | Missense Mutation (SNP) | VAF 106/1126 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- LTA4H | c.30A>C p.R10S | Missense Mutation (SNP) | VAF 41/786 reads (5%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0); called by muse, mutect2
- MAGEA1 | c.467G>T p.G156V | Missense Mutation (SNP) | VAF 137/322 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- MBD5 | c.909G>T p.L303F | Missense Mutation (SNP) | VAF 214/1044 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- MCM2 | c.1780G>T p.D594Y | Missense Mutation (SNP) | VAF 44/388 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MFN1 | c.175G>A p.G59R | Missense Mutation (SNP) | VAF 57/353 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- MIS18BP1 | c.2962G>A p.D988N | Missense Mutation (SNP) | VAF 42/492 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- MITF | c.616A>G p.S206G (on ENST00000448226 / NM_006722.3; = p.S100G on NM_000248.4) | Missense Mutation (SNP) | VAF 40/970 reads (4%) | SIFT tolerated (0.08); PolyPhen benign (0.007); called by muse, mutect2
- MPHOSPH6 | c.57G>T p.M19I | Missense Mutation (SNP) | VAF 59/313 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.926); called by muse, mutect2, varscan2
- MRC1 | c.1511G>A p.C504Y | Missense Mutation (SNP) | VAF 127/558 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MTMR8 | c.1244G>T p.C415F | Missense Mutation (SNP) | VAF 216/496 reads (44%) | SIFT tolerated (0.33); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- MUC6 | c.4454C>A p.P1485H | Missense Mutation (SNP) | VAF 106/427 reads (25%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.003); called by muse, varscan2
- MYO18A | c.244G>T p.D82Y | Missense Mutation (SNP) | VAF 81/351 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.726); called by muse, mutect2, varscan2
- NADK | c.773G>T p.G258V | Missense Mutation (SNP) | VAF 36/442 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.098); called by muse, mutect2
- NAV3 | c.218A>T p.K73I | Missense Mutation (SNP) | VAF 24/175 reads (14%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- NAV3 | c.5381A>G p.E1794G (on ENST00000397909 / NM_001024383.2; = p.E1772G on NM_014903.6) | Missense Mutation (SNP) | VAF 100/600 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- NCOR2 | c.6770A>C p.K2257T | Missense Mutation (SNP) | VAF 34/578 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- NDST4 | c.589C>A p.P197T | Missense Mutation (SNP) | VAF 85/514 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); called by muse, mutect2, varscan2
- NEK11 | c.640G>C p.D214H | Missense Mutation (SNP) | VAF 14/212 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- NFASC | c.2346G>T p.W782C (on ENST00000339876 / NM_001378329.1; = p.W778C on NM_015090.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 72/339 reads (21%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.502); called by muse, mutect2, varscan2
- NOP9 | c.1754G>T p.G585V | Missense Mutation (SNP) | VAF 6/63 reads (10%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.979); called by muse, mutect2
- NOVA1 | c.1161C>A p.S387R | Missense Mutation (SNP) | VAF 119/772 reads (15%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.571); called by muse, mutect2, varscan2
- NRXN3 | c.732G>C p.E244D (on ENST00000557594 / NM_001272020.2; = p.E876D on NM_004796.6) | Missense Mutation (SNP) | VAF 97/909 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- NUP210L | c.4453G>C p.D1485H | Missense Mutation (SNP) | VAF 60/1202 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); called by muse, mutect2
- NUTM2E | c.1540C>A p.P514T | Missense Mutation (SNP) | VAF 148/1268 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- NXPE4 | c.536T>G p.L179R | Missense Mutation (SNP) | VAF 64/290 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- OBSCN | c.19543A>T p.I6515F | Missense Mutation (SNP) | VAF 85/716 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.713); called by muse, mutect2, varscan2
- OR10Q1 | c.393C>A p.C131* | Nonsense Mutation (SNP) | VAF 46/218 reads (21%) | called by muse, mutect2, varscan2
- OR2A12 | c.813G>T p.K271N | Missense Mutation (SNP) | VAF 34/563 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- OR2L8 | c.835A>G p.I279V | Missense Mutation (SNP) | VAF 98/870 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- OR2T5 | c.97G>T p.V33L | Missense Mutation (SNP) | VAF 66/2034 reads (3%) | SIFT tolerated (0.39); PolyPhen benign (0.001); called by muse, mutect2
- OR4D11 | c.465C>A p.H155Q | Missense Mutation (SNP) | VAF 140/476 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR51A4 | c.921A>T p.K307N | Missense Mutation (SNP) | VAF 28/327 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.111); called by muse, mutect2
- OR6Y1 | c.411C>A p.Y137* | Nonsense Mutation (SNP) | VAF 104/724 reads (14%) | called by muse, mutect2, varscan2
- OXA1L | c.767A>T p.Y256F (on ENST00000285848; = p.Y196F on NM_005015.5) | Missense Mutation (SNP) | VAF 124/389 reads (32%) | SIFT tolerated (0.62); PolyPhen possibly damaging (0.898); called by muse, mutect2, varscan2
- PCK1 | c.1617G>T p.W539C | Missense Mutation (SNP) | VAF 366/1058 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PDZRN4 | c.1352A>C p.D451A (on ENST00000402685 / NM_001164595.2; = p.D193A on NM_013377.4) | Missense Mutation (SNP) | VAF 98/572 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PELP1 | c.2234C>T p.T745I | Missense Mutation (SNP) | VAF 58/244 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.147); called by muse, mutect2, varscan2
- PIP4K2B | c.662C>A p.T221K | Missense Mutation (SNP) | VAF 78/691 reads (11%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.733); called by muse, mutect2, varscan2
- PLA2G2A | c.170A>G p.K57R | Missense Mutation (SNP) | VAF 39/141 reads (28%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.892); called by muse, mutect2, varscan2
- PLXNA1 | c.4214C>A p.T1405K | Missense Mutation (SNP) | VAF 80/479 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.752); called by muse, mutect2, varscan2
- PLXNC1 | c.899T>C p.V300A | Missense Mutation (SNP) | VAF 12/110 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.137); called by muse, mutect2, varscan2
- POTEB3 | c.379G>A p.A127T | Missense Mutation (SNP) | VAF 16/103 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.2); called by mutect2, varscan2
- PPP1R1A | c.121C>A p.L41M | Missense Mutation (SNP) | VAF 130/620 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PROX1 | c.378G>T p.E126D | Missense Mutation (SNP) | VAF 62/210 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- PSMD1 | c.1753A>T p.T585S | Missense Mutation (SNP) | VAF 175/671 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.465); called by muse, mutect2, varscan2
- PTPN4 | c.2375A>G p.Y792C | Missense Mutation (SNP) | VAF 47/434 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- PTPRQ | c.6107T>A p.F2036Y (on ENST00000616559; = p.F2003Y on NM_001145026.2) | Missense Mutation (SNP) | VAF 52/308 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PYDC2 | c.203C>A p.A68E | Missense Mutation (SNP) | VAF 63/554 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.158); called by muse, mutect2, varscan2
- RAD51AP2 | c.2281C>A p.Q761K | Missense Mutation (SNP) | VAF 31/356 reads (9%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.719); called by muse, mutect2
- RADIL | c.269G>T p.R90L | Missense Mutation (SNP) | VAF 150/396 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- RASGRP3 | c.176A>T p.Y59F | Missense Mutation (SNP) | VAF 60/523 reads (11%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- RBM20 | c.1952G>T p.S651I | Missense Mutation (SNP) | VAF 56/263 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- RBMS1 | c.371A>T p.K124M | Missense Mutation (SNP) | VAF 64/417 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- RET | c.1021C>A p.Q341K | Missense Mutation (SNP) | VAF 83/393 reads (21%) | SIFT tolerated (0.93); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- RGPD4 | c.392T>C p.I131T | Missense Mutation (SNP) | VAF 54/888 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.018); called by muse, mutect2
- RNF222 | c.497T>A p.L166Q | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.741); called by muse, mutect2, varscan2
- ROR2 | c.2545C>T p.Q849* | Nonsense Mutation (SNP) | VAF 69/242 reads (29%) | called by muse, mutect2, varscan2
- RPS6KA4 | c.596G>A p.G199D | Missense Mutation (SNP) | VAF 73/279 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SAMD4B | c.1445-1G>C p.X482_splice | Splice Site (SNP) | VAF 110/438 reads (25%) | called by muse, mutect2, varscan2
- SBF2 | c.1106G>A p.G369E | Missense Mutation (SNP) | VAF 30/902 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SCN11A | c.3396C>A p.V1132= | Splice Region (SNP) | VAF 142/359 reads (40%) | called by muse, mutect2, varscan2
- SELENOO | c.1689-2A>T p.X563_splice | Splice Site (SNP) | VAF 32/152 reads (21%) | called by muse, mutect2, varscan2
- SHTN1 | c.220G>T p.E74* | Nonsense Mutation (SNP) | VAF 84/477 reads (18%) | called by muse, mutect2, varscan2
- SI | c.827del p.G276Afs*21 | Frame Shift Del (DEL) | VAF 58/407 reads (14%) | called by mutect2, pindel, varscan2
- SKIDA1 | c.2153T>G p.F718C | Missense Mutation (SNP) | VAF 60/675 reads (9%) | SIFT tolerated (0.23); PolyPhen benign (0.006); called by muse, mutect2
- SLC12A5 | c.1154A>C p.Y385S (on ENST00000454036 / NM_001134771.2; = p.Y362S on NM_020708.5) | Missense Mutation (SNP) | VAF 25/261 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.624); called by muse, mutect2
- SLC22A25 | c.1031C>G p.P344R | Missense Mutation (SNP) | VAF 113/400 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.744); called by muse, mutect2, varscan2
- SLC6A14 | c.823G>T p.V275F | Missense Mutation (SNP) | VAF 165/341 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- SLC7A10 | c.703G>T p.A235S | Missense Mutation (SNP) | VAF 112/421 reads (27%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SLC9A4 | c.721-6_723delinsTTTTTTTTT p.X241_splice | Splice Site (ONP) | VAF 6/69 reads (9%) | called by mutect2*, pindel
- SLC9C2 | c.2640G>T p.K880N | Missense Mutation (SNP) | VAF 49/369 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- SMG7 | c.295A>G p.S99G | Missense Mutation (SNP) | VAF 213/576 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- SMTNL1 | c.736G>T p.G246W (on ENST00000399154; = p.G283W on NM_001105565.2) | Missense Mutation (SNP) | VAF 18/202 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2
- SMURF2 | c.574G>T p.A192S | Missense Mutation (SNP) | VAF 149/496 reads (30%) | SIFT tolerated (0.32); PolyPhen benign (0.434); called by muse, mutect2, varscan2
- SMYD2 | c.752A>G p.N251S | Missense Mutation (SNP) | VAF 67/359 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- SNAP25 | c.163G>A p.E55K | Missense Mutation (SNP) | VAF 38/422 reads (9%) | SIFT tolerated (0.05); PolyPhen benign (0.316); called by muse, mutect2
- SORL1 | c.3955C>G p.P1319A | Missense Mutation (SNP) | VAF 35/436 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.046); called by muse, mutect2
- SPATA31A1 | c.3066G>C p.E1022D | Missense Mutation (SNP) | VAF 96/328 reads (29%) | SIFT tolerated (0.27); PolyPhen benign (0.012); called by mutect2, varscan2
- SPEG | c.1598C>G p.P533R | Missense Mutation (SNP) | VAF 13/115 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.642); called by muse, mutect2, varscan2
- SPTA1 | c.5565+1G>T p.X1855_splice | Splice Site (SNP) | VAF 105/920 reads (11%) | called by muse, mutect2, varscan2
- SPTBN4 | c.2440C>T p.Q814* | Nonsense Mutation (SNP) | VAF 57/230 reads (25%) | called by muse, mutect2, varscan2
- SPTLC3 | c.428G>A p.R143K | Missense Mutation (SNP) | VAF 28/234 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.32); called by muse, varscan2
- SSTR3 | c.508G>T p.A170S | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.155); called by muse, mutect2, varscan2
- SYN2 | c.342G>T p.K114N | Missense Mutation (SNP) | VAF 97/208 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.739); called by muse, mutect2, varscan2
- TDRD15 | c.1974A>T p.Q658H | Missense Mutation (SNP) | VAF 65/285 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.342); called by muse, mutect2, varscan2
- TEX47 | c.436T>C p.W146R | Missense Mutation (SNP) | VAF 156/534 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TIE1 | c.2T>A p.M1? | Translation Start Site (SNP) | VAF 113/349 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.599); called by muse, mutect2, varscan2
- TJP1 | c.862G>T p.D288Y | Missense Mutation (SNP) | VAF 32/142 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); called by muse, mutect2
- TMEM237 | c.575G>T p.R192L (on ENST00000409883 / NM_001044385.3; = p.R184L on NM_152388.4) | Missense Mutation (SNP) | VAF 240/1040 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TMEM252 | c.148G>T p.G50W | Missense Mutation (SNP) | VAF 245/1035 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TMEM94 | c.2170C>T p.P724S | Missense Mutation (SNP) | VAF 117/747 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- TRAF1 | c.857del p.G286Afs*26 | Frame Shift Del (DEL) | VAF 78/291 reads (27%) | called by mutect2, pindel, varscan2
- TRAPPC12 | c.1111G>C p.V371L | Missense Mutation (SNP) | VAF 84/290 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.683); called by muse, mutect2, varscan2
- TRAV1-1 | c.157C>A p.Q53K | Missense Mutation (SNP) | VAF 58/754 reads (8%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.521); called by muse, mutect2
- TRIM58 | c.1416G>T p.R472S | Missense Mutation (SNP) | VAF 100/300 reads (33%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0); called by muse, mutect2
- TRMT11 | c.73-1G>A p.X25_splice | Splice Site (SNP) | VAF 123/451 reads (27%) | called by muse, mutect2, varscan2
- TRPA1 | c.571C>A p.P191T | Missense Mutation (SNP) | VAF 101/516 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.223); called by muse, mutect2
- TRPC3 | c.2533C>A p.P845T (on ENST00000379645 / NM_001366479.2; = p.P772T on NM_003305.2) | Missense Mutation (SNP) | VAF 107/541 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- TRPV3 | c.1531del p.S511Rfs*23 | Frame Shift Del (DEL) | VAF 66/302 reads (22%) | called by mutect2, pindel, varscan2
- TRRAP | c.9517C>A p.L3173M (on ENST00000359863 / NM_001244580.1; = p.L3144M on NM_003496.3) | Missense Mutation (SNP) | VAF 103/865 reads (12%) | SIFT tolerated (0.76); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- TSHZ3 | c.1841T>A p.V614E | Missense Mutation (SNP) | VAF 53/263 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- TTN | c.86627C>A p.T28876K (on ENST00000591111; = p.T21452K on NM_003319.4) | Missense Mutation (SNP) | VAF 194/982 reads (20%) | PolyPhen probably damaging (0.997); called by mutect2, varscan2
- TUBA1A | c.526C>T p.Q176* | Nonsense Mutation (SNP) | VAF 99/505 reads (20%) | called by muse, mutect2, varscan2
- UCP2 | c.688G>A p.V230I | Missense Mutation (SNP) | VAF 143/499 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- UNC80 | c.8941A>G p.S2981G | Missense Mutation (SNP) | VAF 50/351 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- USP47 | c.512G>T p.S171I (on ENST00000399455 / NM_001372095.1; = p.S83I on NM_017944.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 88/341 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- VCAM1 | c.620T>A p.V207E | Missense Mutation (SNP) | VAF 40/264 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- VPS41 | c.2020A>T p.M674L | Missense Mutation (SNP) | VAF 50/694 reads (7%) | SIFT tolerated (0.61); PolyPhen benign (0); called by muse, mutect2
- WDR62 | c.643A>G p.T215A | Missense Mutation (SNP) | VAF 306/1571 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); called by muse, mutect2, varscan2
- XDH | c.3153del p.S1052Vfs*4 | Frame Shift Del (DEL) | VAF 44/194 reads (23%) | called by mutect2, pindel, varscan2
- ZAN | c.3349T>G p.C1117G | Missense Mutation (SNP) | VAF 17/327 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ZDBF2 | c.5984C>T p.S1995L | Missense Mutation (SNP) | VAF 65/448 reads (15%) | SIFT tolerated (0.19); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- ZDHHC8 | c.1765C>T p.Q589* | Nonsense Mutation (SNP) | VAF 10/110 reads (9%) | called by muse, mutect2
- ZFHX4 | c.3279C>A p.N1093K | Missense Mutation (SNP) | VAF 190/532 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZNF292 | c.2146G>A p.E716K | Missense Mutation (SNP) | VAF 97/366 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- ZNF30 | c.626G>C p.C209S | Missense Mutation (SNP) | VAF 88/348 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.762); called by muse, mutect2, varscan2
- ZNF30 | c.1504C>G p.H502D | Missense Mutation (SNP) | VAF 107/358 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- ZNF679 | c.752G>C p.W251S | Missense Mutation (SNP) | VAF 19/212 reads (9%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.713); called by muse, mutect2
- ZNF713 | c.442A>G p.K148E (on ENST00000633730 / NM_001366796.2; = p.K161E on NM_182633.3) | Missense Mutation (SNP) | VAF 163/398 reads (41%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF782 | c.890A>C p.K297T | Missense Mutation (SNP) | VAF 65/240 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.203); called by muse, mutect2, varscan2
- ZNF804B | c.463A>T p.N155Y | Missense Mutation (SNP) | VAF 63/292 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.459); called by muse, mutect2, varscan2
- ZNF835 | c.173G>A p.S58N | Missense Mutation (SNP) | VAF 183/662 reads (28%) | SIFT tolerated (0.57); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- ZSWIM4 | c.554G>T p.R185L | Missense Mutation (SNP) | VAF 262/689 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.878); called by muse, mutect2, varscan2
- ZUP1 | c.1420C>T p.P474S | Missense Mutation (SNP) | VAF 73/257 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ABT1 | c.351A>T p.I117= | Silent (SNP) | VAF 51/398 reads (13%) | called by muse, mutect2, varscan2
- ADAMTS16 | c.1569A>T p.G523= | Silent (SNP) | VAF 58/488 reads (12%) | catalogued as rs761983364; called by muse, mutect2, varscan2
- ANK2 | c.1701G>A p.L567= | Silent (SNP) | VAF 181/1098 reads (16%) | catalogued as rs555955030, COSV99999667; called by muse, mutect2, varscan2
- AOX1 | c.930C>T p.L310= | Silent (SNP) | VAF 76/367 reads (21%) | called by muse, mutect2, varscan2
- APC2 | c.1809C>T p.I603= | Silent (SNP) | VAF 16/210 reads (8%) | called by muse, mutect2
- ASB10 | c.813C>A p.A271= (on ENST00000420175 / NM_001142459.2; = p.A256= on NM_080871.4) | Silent (SNP) | VAF 33/472 reads (7%) | called by muse, mutect2
- ASTN2 | c.1356C>A p.G452= (on ENST00000313400 / NM_001365069.1; = p.G401= on NM_014010.5) | Silent (SNP) | VAF 96/323 reads (30%) | catalogued as COSV100529525; called by muse, mutect2, varscan2
- ATP10D | c.1938A>G p.K646= | Silent (SNP) | VAF 119/713 reads (17%) | called by muse, mutect2, varscan2
- AVPR1B | c.369C>T p.Y123= | Silent (SNP) | VAF 22/272 reads (8%) | catalogued as rs782107640; called by muse, mutect2
- BCL9L | c.297A>G p.A99= | Silent (SNP) | VAF 41/177 reads (23%) | called by muse, mutect2, varscan2
- C4orf54 | c.4839C>T p.L1613= | Silent (SNP) | VAF 29/318 reads (9%) | called by muse, mutect2
- CBFA2T3 | c.1722C>T p.R574= | Silent (SNP) | VAF 63/434 reads (15%) | called by muse, mutect2, varscan2
- CD2 | c.702C>A p.I234= | Silent (SNP) | VAF 250/711 reads (35%) | called by muse, mutect2, varscan2
- CD36 | c.1233G>T p.V411= | Silent (SNP) | VAF 217/755 reads (29%) | called by muse, mutect2, varscan2
- CD68 | c.135C>T p.S45= | Silent (SNP) | VAF 205/718 reads (29%) | catalogued as rs779285495; called by muse, mutect2, varscan2
- CHST6 | c.621G>A p.V207= | Silent (SNP) | VAF 62/331 reads (19%) | catalogued as rs775009315, COSV60000984; ClinVar: likely benign; called by muse, mutect2, varscan2
- CLUH | c.3345C>T p.H1115= (on ENST00000435359; = p.H1154= on NM_015229.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 8/82 reads (10%) | catalogued as rs1173476195, COSV70930284; called by muse, mutect2, varscan2
- COL6A3 | c.4200G>A p.L1400= | Silent (SNP) | VAF 39/272 reads (14%) | called by muse, mutect2, varscan2
- DCXR | c.309C>A p.S103= | Silent (SNP) | VAF 444/2249 reads (20%) | called by muse, mutect2, varscan2
- DGCR6L | c.480G>A p.G160= | Silent (SNP) | VAF 121/924 reads (13%) | catalogued as COSV99956836; called by muse, mutect2, varscan2
- DLX5 | c.450C>A p.A150= | Silent (SNP) | VAF 428/1867 reads (23%) | called by muse, mutect2, varscan2
- FBXO8 | c.75C>T p.L25= | Silent (SNP) | VAF 105/463 reads (23%) | called by muse, mutect2, varscan2
- FCGR2B | c.234G>A p.E78= | Silent (SNP) | VAF 171/1592 reads (11%) | called by muse, mutect2, varscan2
- FOXI2 | c.444C>T p.N148= | Silent (SNP) | VAF 170/908 reads (19%) | called by muse, mutect2, varscan2
- FPR2 | c.1020T>A p.A340= | Silent (SNP) | VAF 61/170 reads (36%) | called by muse, varscan2
- GLP1R | c.498C>A p.L166= | Silent (SNP) | VAF 77/300 reads (26%) | catalogued as rs1393390591; called by muse, mutect2, varscan2
- GPATCH2L | c.1305G>A p.V435= | Silent (SNP) | VAF 18/249 reads (7%) | catalogued as rs1390132505; called by muse, mutect2
- GPR12 | c.276G>T p.L92= | Silent (SNP) | VAF 103/577 reads (18%) | catalogued as COSV67344631; called by muse, mutect2, varscan2
- GPR4 | c.771C>T p.D257= | Silent (SNP) | VAF 73/223 reads (33%) | called by muse, mutect2, varscan2
- GRAMD1B | c.1413C>T p.D471= | Silent (SNP) | VAF 82/470 reads (17%) | catalogued as rs1301385664, COSV59200091; called by muse, mutect2, varscan2
- HECTD1 | c.4101C>T p.N1367= | Silent (SNP) | VAF 30/340 reads (9%) | catalogued as COSV67948365; called by muse, mutect2
- HMCN1 | c.5280C>T p.G1760= | Silent (SNP) | VAF 185/1454 reads (13%) | catalogued as rs530073498; called by muse, mutect2, varscan2
- HMCN1 | c.5400A>C p.T1800= | Silent (SNP) | VAF 160/1037 reads (15%) | called by muse, mutect2, varscan2
- HOXC6 | c.339C>A p.P113= | Silent (SNP) | VAF 287/734 reads (39%) | catalogued as rs771424142; called by muse, mutect2, varscan2
- IL5RA | c.6C>T p.I2= | Silent (SNP) | VAF 62/278 reads (22%) | called by muse, mutect2, varscan2
- IRX4 | c.1212G>T p.A404= | Silent (SNP) | VAF 22/117 reads (19%) | catalogued as COSV51473194; called by muse, mutect2, varscan2
- ITGA6 | c.267C>T p.T89= | Silent (SNP) | VAF 218/1306 reads (17%) | catalogued as rs748713488; called by muse, mutect2, varscan2
- KRTAP10-11 | c.603C>T p.P201= | Silent (SNP) | VAF 214/930 reads (23%) | catalogued as rs782710016; called by muse, mutect2, varscan2
- LPCAT3 | c.849A>G p.K283= | Silent (SNP) | VAF 132/627 reads (21%) | called by muse, mutect2, varscan2
- LRRC8D | c.1875C>A p.L625= | Silent (SNP) | VAF 182/474 reads (38%) | called by muse, mutect2, varscan2
- MCM3 | c.669C>G p.L223= (on ENST00000229854 / NM_001366374.2; = p.L213= on NM_002388.6 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 40/699 reads (6%) | catalogued as rs553819985; called by muse, mutect2
- MESP1 | c.300C>A p.R100= | Silent (SNP) | VAF 23/76 reads (30%) | called by muse, mutect2, varscan2
- MUSK | c.90C>T p.I30= | Silent (SNP) | VAF 94/292 reads (32%) | called by muse, mutect2, varscan2
- MYO15B | c.5973G>A p.A1991= | Silent (SNP) | VAF 62/285 reads (22%) | catalogued as rs914586712; called by muse, mutect2, varscan2
- NBPF26 | c.4158G>C p.L1386= (on ENST00000620612; = p.L1124= on NM_001351372.1) | Silent (SNP) | VAF 343/728 reads (47%) | catalogued as rs1553273445; called by muse, mutect2, varscan2
- NCAPG2 | c.2610G>A p.L870= | Silent (SNP) | VAF 71/262 reads (27%) | called by muse, mutect2, varscan2
- NOS1 | c.2733G>A p.L911= | Silent (SNP) | VAF 67/338 reads (20%) | catalogued as COSV57612999; called by muse, mutect2, varscan2
- NRK | c.1167C>T p.P389= | Silent (SNP) | VAF 51/130 reads (39%) | catalogued as COSV99687001; called by muse, mutect2, varscan2
- OBSCN | c.3186C>A p.S1062= | Silent (SNP) | VAF 15/132 reads (11%) | called by muse, mutect2, varscan2
- ONECUT2 | c.753G>C p.P251= | Silent (SNP) | VAF 41/169 reads (24%) | called by muse, mutect2, varscan2
- OR14C36 | c.108T>C p.T36= | Silent (SNP) | VAF 38/351 reads (11%) | called by muse, mutect2, varscan2
- OR1C1 | c.744G>A p.V248= | Silent (SNP) | VAF 39/234 reads (17%) | catalogued as COSV101376195; called by muse, mutect2, varscan2
- OR2M3 | c.810G>A p.Q270= | Silent (SNP) | VAF 69/1052 reads (7%) | catalogued as COSV71758875; called by muse, mutect2
- OR52A5 | c.363C>A p.A121= | Silent (SNP) | VAF 110/327 reads (34%) | catalogued as rs1400762308; called by muse, mutect2, varscan2
- P2RY2 | c.441C>T p.A147= | Silent (SNP) | VAF 4/10 reads (40%) | called by mutect2, varscan2
- PARP3 | c.807G>A p.Q269= | Silent (SNP) | VAF 127/402 reads (32%) | called by muse, mutect2, varscan2
- PAX4 | c.750C>A p.A250= | Silent (SNP) | VAF 405/1073 reads (38%) | called by muse, mutect2, varscan2
- PCDHB6 | c.1356C>A p.T452= | Silent (SNP) | VAF 325/1552 reads (21%) | called by muse, mutect2, varscan2
- PCNX2 | c.2910G>T p.P970= | Silent (SNP) | VAF 42/500 reads (8%) | called by muse, mutect2
- PLXNA2 | c.2592G>A p.L864= | Silent (SNP) | VAF 28/364 reads (8%) | called by muse, mutect2
- PNLIP | c.945T>C p.P315= | Silent (SNP) | VAF 65/300 reads (22%) | called by muse, mutect2, varscan2
- PNLIPRP1 | c.396C>T p.T132= | Silent (SNP) | VAF 82/655 reads (13%) | catalogued as rs782756444; called by muse, mutect2, varscan2
- POMC | c.747C>T p.P249= | Silent (SNP) | VAF 100/298 reads (34%) | catalogued as rs370416211, COSV53035186; called by muse, mutect2, varscan2
- POR | c.345G>T p.A115= | Silent (SNP) | VAF 20/331 reads (6%) | catalogued as COSV67518659; called by muse, mutect2
- PPFIA3 | c.1968C>A p.P656= | Silent (SNP) | VAF 72/192 reads (38%) | catalogued as COSV61949724; called by muse, mutect2, varscan2
- RASGRP1 | c.918C>T p.I306= | Silent (SNP) | VAF 78/489 reads (16%) | called by muse, mutect2, varscan2
- RHBDD1 | c.6A>G p.Q2= | Silent (SNP) | VAF 48/176 reads (27%) | catalogued as rs374371418; called by muse, mutect2
- RIN2 | c.2079G>T p.P693= (on ENST00000255006 / NM_001242581.1; = p.P644= on NM_018993.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 173/860 reads (20%) | called by muse, mutect2, varscan2
- SCFD2 | c.108G>T p.L36= | Silent (SNP) | VAF 15/293 reads (5%) | catalogued as COSV66375066; called by muse, mutect2
- SEC24D | c.741A>G p.A247= | Silent (SNP) | VAF 37/459 reads (8%) | catalogued as rs746742192; called by muse, mutect2
- SHOX2 | c.865C>T p.L289= (on ENST00000441443 / NM_006884.3; = p.L313= on NM_003030.4) | Silent (SNP) | VAF 98/456 reads (21%) | called by muse, mutect2, varscan2
- SLC26A8 | c.2760T>A p.A920= | Silent (SNP) | VAF 92/717 reads (13%) | called by muse, mutect2, varscan2
- SLC38A8 | c.123C>A p.G41= | Silent (SNP) | VAF 38/263 reads (14%) | catalogued as rs757575334; called by muse, mutect2, varscan2
- SLC41A3 | c.336G>A p.L112= | Silent (SNP) | VAF 30/290 reads (10%) | called by muse, mutect2
- SLC5A11 | c.285C>A p.G95= | Silent (SNP) | VAF 52/384 reads (14%) | called by muse, mutect2, varscan2
- SLC9A2 | c.1401C>A p.V467= | Silent (SNP) | VAF 42/570 reads (7%) | called by muse, mutect2
- SORCS3 | c.3006C>A p.S1002= | Silent (SNP) | VAF 36/223 reads (16%) | catalogued as COSV63795597; called by muse, mutect2, varscan2
- SPEG | c.1599C>G p.P533= | Silent (SNP) | VAF 13/115 reads (11%) | called by muse, mutect2, varscan2
- SPEM1 | c.405G>A p.E135= | Silent (SNP) | VAF 104/400 reads (26%) | called by muse, mutect2, varscan2
- SRRT | c.2412G>T p.P804= | Silent (SNP) | VAF 47/151 reads (31%) | called by muse, mutect2, varscan2
- STK32B | c.1221C>T p.T407= | Silent (SNP) | VAF 27/205 reads (13%) | called by muse, mutect2, varscan2
- SULT2A1 | c.318C>A p.P106= | Silent (SNP) | VAF 103/287 reads (36%) | catalogued as COSV99705477; called by muse, mutect2, varscan2
- TBC1D10C | c.492C>G p.L164= | Silent (SNP) | VAF 22/336 reads (7%) | called by muse, mutect2
- TEX13C | c.2911C>A p.R971= | Silent (SNP) | VAF 117/286 reads (41%) | called by muse, mutect2, varscan2
- TRPA1 | c.573A>G p.P191= | Silent (SNP) | VAF 102/514 reads (20%) | called by muse, mutect2
- TSHZ3 | c.1953G>T p.G651= | Silent (SNP) | VAF 8/40 reads (20%) | catalogued as COSV53665340; called by muse, mutect2
- TSPAN14 | c.198G>A p.L66= | Silent (SNP) | VAF 202/1000 reads (20%) | called by muse, mutect2, varscan2
- TTC7B | c.1443T>C p.S481= | Silent (SNP) | VAF 130/673 reads (19%) | called by muse, mutect2, varscan2
- TTN | c.90681G>A p.L30227= (on ENST00000591111; = p.L22803= on NM_003319.4) | Silent (SNP) | VAF 86/429 reads (20%) | called by muse, mutect2, varscan2
- WDFY4 | c.5373A>G p.A1791= | Silent (SNP) | VAF 73/420 reads (17%) | called by muse, mutect2, varscan2
- YY1 | c.633G>A p.Q211= | Silent (SNP) | VAF 46/362 reads (13%) | called by muse, mutect2, varscan2
- ZNF208 | c.2445T>C p.S815= | Silent (SNP) | VAF 135/473 reads (29%) | called by muse, mutect2, varscan2
- ZNF791 | c.1254A>T p.A418= | Silent (SNP) | VAF 56/206 reads (27%) | called by muse, mutect2, varscan2
- AC024651.2 | chr15:97873995 C>T | 5'Flank (SNP) | VAF 92/303 reads (30%) | called by mutect2, varscan2
- AC103993.1 | n.133A>T | RNA (SNP) | VAF 82/359 reads (23%) | called by muse, mutect2, varscan2
- AC132807.2 | n.52G>T | RNA (SNP) | VAF 9/51 reads (18%) | called by muse, mutect2, varscan2
- ADD1 | c.1161+108C>T | Intron (SNP) | VAF 18/162 reads (11%) | called by muse, varscan2
- ADGRD1 | c.1027-405G>T | Intron (SNP) | VAF 21/100 reads (21%) | called by muse, mutect2, varscan2
- AMPH | c.1159-9C>A | Intron (SNP) | VAF 80/308 reads (26%) | catalogued as COSV57731538; called by muse, varscan2
- ARSD | c.195-1218C>G | Intron (SNP) | VAF 29/74 reads (39%) | called by muse, mutect2, varscan2
- ASPDH | c.-21C>A | 5'UTR (SNP) | VAF 51/150 reads (34%) | called by muse, mutect2, varscan2
- ASPDH | c.-22C>A | 5'UTR (SNP) | VAF 49/145 reads (34%) | catalogued as rs576379216; called by muse, mutect2, varscan2
- ATP1A2 | c.3034+36G>A | Intron (SNP) | VAF 127/582 reads (22%) | catalogued as rs1558010403; called by muse, mutect2, varscan2
- CACNA1C | c.3913-6750C>A | Intron (SNP) | VAF 110/605 reads (18%) | called by muse, mutect2, varscan2
- CCDC115 | c.-33G>A | 5'UTR (SNP) | VAF 71/407 reads (17%) | catalogued as rs375455175; called by muse, mutect2, varscan2
- CCDC144CP | n.1740G>A | RNA (SNP) | VAF 115/413 reads (28%) | called by muse, mutect2, varscan2
- CCDC33 | c.1938+411G>A | Intron (SNP) | VAF 177/621 reads (29%) | catalogued as rs748787379; called by muse, mutect2, varscan2
- CCDC7 | c.1134+19_1134+20del | Intron (DEL) | VAF 44/306 reads (14%) | called by pindel, varscan2
- CCN6 | c.49-956T>A | Intron (SNP) | VAF 179/662 reads (27%) | called by muse, mutect2, varscan2
- CD247 | c.336+503G>T | Intron (SNP) | VAF 388/3140 reads (12%) | called by muse, varscan2
- CHRNA4 | c.*42G>A | 3'UTR (SNP) | VAF 86/1727 reads (5%) | catalogued as rs200167733; called by muse, mutect2
- COL20A1 | c.3295-160C>G | Intron (SNP) | VAF 70/323 reads (22%) | called by muse, mutect2, varscan2
- CTHRC1 | c.-5G>A | 5'UTR (SNP) | VAF 52/225 reads (23%) | catalogued as rs779702818; called by muse, mutect2, varscan2
- CXCL12 | c.*371C>T | 3'UTR (SNP) | VAF 113/642 reads (18%) | called by muse, mutect2, varscan2
- DCAF17 | c.*2242G>T | 3'UTR (SNP) | VAF 123/643 reads (19%) | called by muse, mutect2, varscan2
- DCXR | c.*47C>T | 3'UTR (SNP) | VAF 174/918 reads (19%) | called by muse, mutect2, varscan2
- DGKB | c.2126-31312C>A | Intron (SNP) | VAF 214/672 reads (32%) | called by muse, mutect2, varscan2
- DNHD1 | c.2998+54del | Intron (DEL) | VAF 25/89 reads (28%) | called by mutect2, pindel, varscan2
- DPY19L2P1 | n.1831C>A | RNA (SNP) | VAF 210/602 reads (35%) | called by muse, varscan2
- DYRK1A | c.-11G>A | 5'UTR (SNP) | VAF 92/372 reads (25%) | called by muse, mutect2, varscan2
- FAM157A | chr3:198167724 A>T | 5'Flank (SNP) | VAF 95/687 reads (14%) | called by muse, mutect2, varscan2
- FAM183BP | n.1121C>T | RNA (SNP) | VAF 81/759 reads (11%) | catalogued as rs779795402; called by muse, mutect2, varscan2
- FAS | c.*1077T>A | 3'UTR (SNP) | VAF 102/977 reads (10%) | called by muse, mutect2, varscan2
- FKBP9P1 | chr7:55691425 C>T | 5'Flank (SNP) | VAF 87/553 reads (16%) | called by muse, mutect2, varscan2
- FMO6P | n.1876A>T | RNA (SNP) | VAF 27/277 reads (10%) | called by muse, mutect2, varscan2
- FOXP2 | c.*752A>G | 3'UTR (SNP) | VAF 62/850 reads (7%) | catalogued as rs1377157062; called by muse, mutect2
- HLA-B | c.343+12C>T | Intron (SNP) | VAF 88/299 reads (29%) | called by muse, mutect2, varscan2
- HNF4A-AS1 | n.356+1358C>G | Intron (SNP) | VAF 40/444 reads (9%) | called by muse, mutect2
- IL7 | c.*7T>A | 3'UTR (SNP) | VAF 131/493 reads (27%) | catalogued as COSV99804823; called by muse, mutect2, varscan2
- ISL1 | c.*5C>T | 3'UTR (SNP) | VAF 102/576 reads (18%) | catalogued as rs1351568124; called by muse, varscan2
- LEPROT | chr1:65420638 C>T | 5'Flank (SNP) | VAF 20/177 reads (11%) | called by muse, mutect2, varscan2
- LINC01036 | n.277G>A | RNA (SNP) | VAF 139/1158 reads (12%) | called by muse, mutect2, varscan2
- LINC01342 | n.573G>A | RNA (SNP) | VAF 34/367 reads (9%) | called by muse, mutect2
- LNPK | c.1055-1942C>T | Intron (SNP) | VAF 68/428 reads (16%) | called by muse, mutect2, varscan2
- LPP | c.1241-13622G>A | Intron (SNP) | VAF 49/335 reads (15%) | called by muse, mutect2, varscan2
- LRP12 | chr8:104484377 C>T | 3'Flank (SNP) | VAF 34/606 reads (6%) | catalogued as rs1056333167; called by muse, mutect2
- MIR516A2 | n.77G>T | RNA (SNP) | VAF 84/248 reads (34%) | called by muse, mutect2, varscan2
- MKS1 | c.*463G>T | 3'UTR (SNP) | VAF 244/1023 reads (24%) | called by muse, mutect2, varscan2
- MLLT10 | c.796-1448G>T | Intron (SNP) | VAF 78/386 reads (20%) | called by muse, mutect2, varscan2
- MYO1F | c.1610+16C>A | Intron (SNP) | VAF 158/530 reads (30%) | called by muse, mutect2, varscan2
- NDRG4 | c.-42C>T | 5'UTR (SNP) | VAF 12/84 reads (14%) | called by muse, mutect2
- NDUFB5 | chr3:179604754 G>T | 5'Flank (SNP) | VAF 15/233 reads (6%) | called by muse, mutect2
- NUP214 | c.-35A>T | 5'UTR (SNP) | VAF 40/127 reads (31%) | called by muse, mutect2, varscan2
- OR52B1P | n.673A>T | RNA (SNP) | VAF 133/422 reads (32%) | called by muse, mutect2, varscan2
- PENK | c.138+103G>T | Intron (SNP) | VAF 24/78 reads (31%) | catalogued as rs775249263; called by muse, mutect2, varscan2
- PIK3C3 | c.2264-21G>T | Intron (SNP) | VAF 42/572 reads (7%) | catalogued as rs374275009; called by muse, mutect2
- PKD1L1 | c.6965+1558C>T | Intron (SNP) | VAF 139/356 reads (39%) | catalogued as COSV51843863; called by muse, mutect2, varscan2
- REXO1L1P | chr8:85655126 G>C | 3'Flank (SNP) | VAF 174/3022 reads (6%) | catalogued as rs757610260; called by muse, mutect2
- RPS20 | c.103+146A>G | Intron (SNP) | VAF 83/274 reads (30%) | called by muse, mutect2, varscan2
- SF3B2 | c.180+17G>T | Intron (SNP) | VAF 10/51 reads (20%) | called by muse, mutect2, varscan2
- SLC6A10P | n.3600C>A | RNA (SNP) | VAF 15/100 reads (15%) | called by mutect2, varscan2
- SORBS1 | c.2129-753A>C | Intron (SNP) | VAF 24/408 reads (6%) | called by muse, mutect2
- STPG1 | c.*218A>C | 3'UTR (SNP) | VAF 27/978 reads (3%) | called by muse, mutect2
- SYNE1 | c.16710+28A>C | Intron (SNP) | VAF 99/499 reads (20%) | called by muse, mutect2, varscan2
- TBC1D8B | c.1838-741A>T | Intron (SNP) | VAF 43/154 reads (28%) | called by muse, mutect2, varscan2
- THNSL2 | chr2:88171299 G>T | 5'Flank (SNP) | VAF 70/520 reads (13%) | called by muse, mutect2, varscan2
- TPRXL | n.829C>G | RNA (SNP) | VAF 88/726 reads (12%) | called by muse, varscan2
- TRAF3IP1 | c.-10G>A | 5'UTR (SNP) | VAF 33/140 reads (24%) | catalogued as rs1488887480; called by muse, mutect2
- TTN | c.10361-4095G>T | Intron (SNP) | VAF 73/445 reads (16%) | called by muse, mutect2, varscan2
- UBBP4 | n.749A>T | RNA (SNP) | VAF 108/1272 reads (8%) | called by muse, mutect2
- VPS8 | c.2454+2264A>G | Intron (SNP) | VAF 53/321 reads (17%) | called by muse, mutect2, varscan2
- XIRP2 | c.*1103C>A | 3'UTR (SNP) | VAF 66/450 reads (15%) | called by muse, mutect2, varscan2
- ZFHX3 | c.-533+43T>A | Intron (SNP) | VAF 62/397 reads (16%) | called by muse, mutect2, varscan2
- ZNF433 | c.4-8417A>C | Intron (SNP) | VAF 147/533 reads (28%) | called by muse, mutect2, varscan2
